Somatic mutation profile of tumor specimen MP2PRT-PAVRZK-TMP1-A (aliquot MP2PRT-PAVRZK-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVRZK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,007 days).
Specimen MP2PRT-PAVRZK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d4db11a-1582-4a90-8fa2-c146175c118f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRZK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRZK-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd7867f2-1046-410c-8559-d0010a25fe8d

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.1663G>A p.A555T (on ENST00000506720 / NM_001322402.2; = p.A487T on NM_015236.6) | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.248); catalogued as COSV72231971; called by muse, mutect2, varscan2
- CPO | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs371902561, COSV55941611; called by muse, mutect2, varscan2
- PCDH1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746885; called by muse, mutect2, varscan2
- RIPK4 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs149403548, COSV60187880; called by muse, mutect2
- SETDB1 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as COSV54977443; called by muse, mutect2, varscan2
- ANKRD31 | c.4529G>A p.G1510E | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSND | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 23/585 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.359); called by muse, mutect2
- C5 | c.4435del p.I1479Yfs*50 | Frame Shift Del (DEL) | VAF 77/303 reads (25%) | called by mutect2, pindel, varscan2
- ITPKB | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 135/493 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PENK | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP5C | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PRKAA2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PRPF8 | c.4759G>C p.E1587Q | Missense Mutation (SNP) | VAF 123/397 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG11 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLC5A8 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT20H | c.1975C>T p.Q659* (on ENST00000350612 / NM_001014286.3; = p.Q660* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- TXLNA | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CELF4 | c.1267C>T p.L423= | Silent (SNP) | VAF 74/256 reads (29%) | called by muse, mutect2, varscan2
- HECTD4 | c.2430G>A p.V810= | Silent (SNP) | VAF 12/427 reads (3%) | catalogued as COSV100296138; called by muse, mutect2
- NBEA | c.5109C>T p.L1703= | Silent (SNP) | VAF 81/350 reads (23%) | called by muse, mutect2, varscan2
- NPBWR2 | c.852G>C p.L284= | Silent (SNP) | VAF 38/897 reads (4%) | called by muse, mutect2
- SPATA19 | c.141A>G p.E47= | Silent (SNP) | VAF 68/220 reads (31%) | called by muse, mutect2, varscan2
- GNB1 | c.*1039dup | 3'UTR (INS) | VAF 41/236 reads (17%) | called by mutect2, pindel, varscan2
- IGHV4-61 | chr14:106639118 ins TCCCCTCAACGGCCCCA | 3'Flank (INS) | VAF 17/62 reads (27%) | called by pindel, varscan2
